TCGA case TCGA-A6-A565 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd7a53ee-cb08-40c4-9935-51d1ca17e9e8

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Dead; Days to death: 494 days (1.4 years).

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.4; Tissue or organ of origin: Transverse colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 34.3 years (12,526 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 494 days (1.4 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 13; Lymph nodes tested: 41; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 35.1 years (12,827 days); Days to diagnosis: 301 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 35.5 years (12,965 days); Days to diagnosis: 439 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 301 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 301 days.
- Day 439 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 439 days (1.2 years).
- Days to follow up: 494 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 71.5 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 66.7 kg; Height: 150 cm; BMI: 29.6.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-A565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 550 mg.
  Slide TCGA-A6-A565-01A-01-TS1: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 30; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide TCGA-A6-A565-01A-03-TS3: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-A6-A565-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-A565-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 71.5; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; History colon polyps: No; Colon polyps at procurement indicator: Yes; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: 5FU; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 494 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 494 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 301 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-A565-01A-31D-A28F-01): tumor purity 0.19, ploidy 1.99, whole-genome doublings 0.
